Gene-level copy-number profile of tumor specimen TCGA-94-8491-01A from TCGA case TCGA-94-8491, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.1 years (26,698 days).
Specimen TCGA-94-8491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.140af759-e14f-4748-8902-4034ce9ed66d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-8491-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/158aa217-d24d-444f-a4e4-7f43835c336f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 195; copy number 1: 21,826; copy number 2: 32,438; copy number 3: 3,571; copy number 4: 1,774; copy number 6: 8; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-8491-01A-11D-2322-01): tumor purity 0.52, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:94,618,669–94,739,436, 1 gene (within-gene range 0–1): SLF1.
- chr5:94,788,789–94,793,599, 1 gene: AC008534.1.
- chr8:115,408,496–115,809,673, 2 genes (within-gene range 0–1): TRPS1, AF178030.1.
- chr9:21,695,176–29,318,952, 77 genes (broad region; genes not listed).
- chr11:130,844,191–131,350,917, 8 genes: LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:131,385,249–131,581,145, 3 genes: RNU6ATAC12P, AP003025.1, AP003025.2.
- chr11:134,945,118–135,075,908, 5 genes: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,248,023–10,321,112, 7 genes, copy number 6: TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13.
- chr3:10,330,229–10,330,285, 1 gene, copy number 6: MIR378B.
- chr9:21,638,285–21,638,676, 1 gene, copy number 8: H3P30.

Autosomal genes at a single copy (total copy number 1): 20,025. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
